Gene-level copy-number profile of tumor specimen TCGA-NA-A4R0-01A from TCGA case TCGA-NA-A4R0, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IVB; Age at diagnosis: 80.6 years (29,449 days).
Specimen TCGA-NA-A4R0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.53cce703-0690-4bc5-835e-cc91660c50d3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NA-A4R0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03f303d6-c97d-4f35-8949-5178d6eb09aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 18,266; copy number 2: 38,751; copy number 3: 1,967; copy number 4: 244; copy number 5: 138; copy number 6: 216; copy number 7: 169; copy number 9: 26; copy number 11: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NA-A4R0-01A-11D-A28Q-01): tumor purity 0.29, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:30,718,805–31,146,805, 4 genes (within-gene range 0–1): AC098595.1, PCDH7, AC097716.1, MTCYBP43.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 578 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:44,168,851–44,361,862, 4 genes, copy number 6 (within-gene range 3–6): AC013717.1, RPL12P19, SLC3A1, PREPL.
- chr10:73,742,995–83,736,493, 172 genes, copy number 5–7 (broad region; genes not listed).
- chr12:45,014,672–46,373,778, 24 genes, copy number 11: DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,652,550, 5 genes, copy number 11 (within-gene range 2–11): AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P.
- chr19:34,348,356–41,062,444, 373 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,266. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
